Gene-level copy-number profile of tumor specimen HCM-BROD-0012-C71-01A from HCMI case HCM-BROD-0012-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.8 years (20,744 days).
Specimen HCM-BROD-0012-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4222ac89-473d-45ea-a974-a92a360254ab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0012-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/547ee9bf-a31b-4520-827c-235ec0b25ed3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 4,556; copy number 2: 51,708; copy number 3: 2,067; copy number 4: 21.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,329,665–22,128,103, 33 genes (within-gene range 0–2): KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:39,734,670–40,106,661, 6 genes (within-gene range 0–1): RAB28P1, RBPJP5, GLIDR, BX664615.1, FGF7P3, BX664615.2.
- chr9:39,983,793–40,106,611, 1 gene (within-gene range 0–1): AL772307.1.
- chr9:40,105,822–40,153,147, 4 genes: AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr9:41,890,314–42,354,454, 9 genes (within-gene range 0–2): CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,553. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
